Gene-level copy-number profile of tumor specimen TCGA-3B-A9HJ-01A from TCGA case TCGA-3B-A9HJ, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 68.3 years (24,962 days).
Specimen TCGA-3B-A9HJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.6a00864f-0896-4ab8-8680-8e81fc902a20.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3B-A9HJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b8b9bfa2-c490-46d3-9c48-84e8d0089b0e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,424; copy number 2: 57,232; copy number 3: 151; copy number 4: 4; copy number 5: 8; copy number 9: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3B-A9HJ-01A-11D-A386-01): tumor purity 1, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:67,571,197–67,753,817, 5 genes, copy number 5 (within-gene range 2–5): LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1.
- chr12:76,259,836–76,305,969, 1 gene, copy number 9 (within-gene range 3–9): LNCOG.
- chr12:83,661,009–83,661,719, 1 gene, copy number 5: AC093025.1.
- chr12:89,282,223–89,319,649, 2 genes, copy number 5: RNU7-120P, MRPS6P4.

Autosomal genes at a single copy (total copy number 1): 43. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
